Gene-level copy-number profile of tumor specimen MP2PRT-PASHUI-TMP1-A from MP2PRT case MP2PRT-PASHUI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,865 days).
Specimen MP2PRT-PASHUI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3241ebf7-f79a-4a8c-a780-269fa18dc2da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASHUI-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/31bb16a2-3efe-4932-ad0e-1f7883034936

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 925; copy number 2: 56,765; copy number 3: 715; copy number 4: 25; copy number 5: 50; copy number 6: 85; copy number 7: 21; copy number 8: 87; copy number 9: 27; copy number 10: 170.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,192,500–89,234,912, 6 genes (within-gene range 0–2): IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–1): TRGV5P, TRGV5.
- chr12:131,292,068–131,299,751, 4 genes: RPS6P20, AC092850.1, LINC02415, RNA5SP376.
- chr14:106,714,684–106,775,618, 5 genes: IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 440 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,792,635–13,848,364, 5 genes, copy number 5: FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P.
- chr21:15,694,300–15,696,581, 1 gene, copy number 5: RAD23BP3.
- chr21:18,857,779–19,900,043, 14 genes, copy number 5–7: PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683.
- chr21:20,388,334–20,430,762, 3 genes, copy number 6: FDPSP6, KRT18P2, RPS3AP1.
- chr21:20,651,450–20,828,622, 2 genes, copy number 5: LINC00320, PPIAP1.
- chr21:21,566,763–22,116,605, 7 genes, copy number 6: AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308.
- chr21:23,352,929–24,547,942, 13 genes, copy number 6–8: D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684.
- chr21:25,055,535–43,076,943, 395 genes, copy number 5–10 (within-gene range 4–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
